Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A4T4, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A4T4-01A (Primary Tumor).

Surgical Pathology

Requested By:

TISSUE DESCRIPTION:

A1 A2 B1 B2 C1 C2 C3 D1 D2 E1 F1 F2 F3 F4 F5 F6 G1 H1
Right lower lobe lung (265 grams, 18.0 x 15.0 x 7.0 cm). Tissue from the right upper lobe lung (5.0 x 2.5 x 0.6 cm) and right lower lobe lung (8.0 x 3.3 x 1.5 cm). Superior mediastinal (right lower paratracheal), inferior mediastinal (subcarinal), N1(interlobar, right interlobar) and right middle lobe lymph nodes.

DIAGNOSIS:

Lung, right lower lobe, lobectomy: Invasive grade 4 (of 4) adenocarcinoma, forming a 3.0 x 3.0 x 2.8 cm mass located in the right lower lobe, 6 cm from the bronchial margin. The tumor invades the visceral pleura. The remainder lung parenchyma shows organizing pneumonia. The bronchial margin and multiple (4) intrapulmonary peribronchial lymph nodes are negative for tumor.

Lung, right upper lobe, wedge excision: Organizing pneumonia and subpleural scar.

Lung, right lower lobe, wedge excision: Organizing pneumonia and area of scarring.

Lymph node, N1, excision: A single right interlobar lymph node is involved by metastatic grade 4 (of 4) adenocarcinoma.

Lymph nodes, superior and inferior mediastinal, N1 and right middle lobe, excision: Multiple (10 right lower paratracheal, 3 subcarinal, 1 interlobar, 3 right middle lobe) lymph nodes are negative for tumor.

1CΔ-0-3

adenocarcinoma, NOS 8/40/3
Site: lung, @ lower lobe C34.3

lw
10/29/12

Source: NCI Genomic Data Commons file ab0f45cc-747b-4d02-9cbc-1297f14a3e1a (TCGA-MP-A4T4.30003377-8D42-4189-BCCA-C04AB0669EBC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).